CCDI case PBCDBV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/126a75d6-0068-4fd0-8403-32f7eb512b92

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 15.1 years (5,510 days).

Biospecimens (2 samples)
- Sample 0DPL7G: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPL7O: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
